Somatic mutation profile of tumor specimen ALCH-B400-TTP1-A (aliquot ALCH-B400-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B400, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,219 days).
Specimen ALCH-B400-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 340bb612-f746-4262-b5cd-352f0b8a229e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B400-NB1-A (Blood Derived Normal), aliquot ALCH-B400-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f9acd13-6f9b-4e6a-af29-38dcd2ac4385

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV101549733; called by muse, varscan2
- CCN4 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51531992; called by muse, mutect2
- CHRDL1 | c.870G>T p.E290D (on ENST00000372045; = p.E296D on NM_145234.4) | Missense Mutation (SNP) | VAF 20/754 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV54329431; called by muse, mutect2
- P2RY1 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.697); catalogued as rs1454794599, COSV59309323; called by muse, mutect2
- LRRC42 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- RNF121 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- ZMIZ2 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.067); called by muse, mutect2
- CCDC40 | c.2172G>A p.E724= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- PDE4A | c.645C>A p.T215= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- SEPTIN10 | c.363G>A p.L121= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- ACAP2 | c.286-10816G>T | Intron (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- FMR1 | c.1472-39A>T | Intron (SNP) | VAF 8/133 reads (6%) | catalogued as rs1167026205, COSV54424178; called by muse, mutect2
- GNG2 | c.-29-34212C>A | Intron (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- TMEM183B | n.359G>A | RNA (SNP) | VAF 14/300 reads (5%) | catalogued as COSV60378392; called by muse, mutect2
